Somatic mutation profile of tumor specimen TCGA-A2-A0CL-01A (aliquot TCGA-A2-A0CL-01A-11D-A10Y-09) from TCGA case TCGA-A2-A0CL, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 37.1 years (13,556 days).
Specimen TCGA-A2-A0CL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 542d05d1-26fa-465a-af55-d30115bec91f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0CL-10A (Blood Derived Normal), aliquot TCGA-A2-A0CL-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4aad13c4-53ed-4766-b0da-e379f6ccb4b9

The open-access MAF lists 147 somatic variants for this specimen: 108 protein-altering or splice-affecting, 36 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 36, Nonsense Mutation 22, Splice Site 1, 3'UTR 1, RNA 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 39/216 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.2194C>G p.Q732E (on ENST00000272895 / NM_173076.3; = p.Q414E on NM_015657.3) | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV99787762; called by muse, mutect2
- ABCC9 | c.3496A>T p.S1166C | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as COSV99684071; called by muse, mutect2
- ADAM8 | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1415777665, COSV101291585, COSV69865041; called by muse, mutect2, varscan2
- AHI1 | c.3220C>A p.R1074S | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99661767; called by muse, mutect2
- AKAP13 | c.5195C>T p.P1732L (on ENST00000394518 / NM_007200.5; = p.P1736L on NM_006738.6) | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100772892; called by muse, mutect2
- ANAPC5 | c.351T>G p.D117E | Missense Mutation (SNP) | VAF 6/153 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV99945879; called by muse, mutect2
- ANKRD45 | c.47C>G p.S16* | Nonsense Mutation (SNP) | VAF 14/242 reads (6%) | catalogued as rs749027873, COSV100322341; called by muse, mutect2
- ARHGAP39 | c.2193G>T p.M731I | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV99430104; called by muse, mutect2
- ARHGEF11 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.815); catalogued as COSV100809537; called by muse, mutect2
- ATAD5 | c.1648C>G p.L550V | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV100429550; called by muse, mutect2
- ATN1 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV63112140; called by muse, mutect2, varscan2
- BACH2 | c.2050G>T p.E684* | Nonsense Mutation (SNP) | VAF 8/184 reads (4%) | catalogued as COSV99997686; called by muse, mutect2
- CARD10 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV52658500; called by muse, mutect2, varscan2
- CCL25 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.094); catalogued as COSV99495051; called by muse, mutect2
- CD163 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.841); catalogued as COSV100775577; called by muse, mutect2
- CELA2A | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 11/234 reads (5%) | catalogued as COSV100657469; called by muse, mutect2
- CEP135 | c.2863C>T p.R955* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as COSV57261536; called by muse, mutect2
- CEP76 | c.784C>G p.Q262E | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100042560; called by muse, mutect2
- CHD4 | c.3145C>G p.L1049V (on ENST00000357008 / NM_001363606.2; = p.L1062V on NM_001273.5) | Missense Mutation (SNP) | VAF 8/197 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100537149; called by muse, mutect2
- CHMP5 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV99794473; called by muse, mutect2
- CLK2 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1188249873, COSV100751772; called by muse, mutect2
- CSE1L | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99521762, COSV99521765; called by muse, mutect2
- DDX43 | c.648G>C p.W216C | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100946188; called by muse, mutect2
- DDX50 | c.1815G>A p.W605* | Nonsense Mutation (SNP) | VAF 8/210 reads (4%) | catalogued as COSV101007170; called by muse, mutect2
- DDX6 | c.602G>C p.G201A | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99869870; called by muse, mutect2
- DGKB | c.1719G>C p.E573D | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.704); catalogued as COSV51779584, COSV51831555; called by muse, mutect2
- DMXL2 | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.1); catalogued as COSV99195909; called by muse, mutect2
- DNAH2 | c.4763C>T p.S1588L | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1484561018, COSV66715954, COSV66720305; called by muse, mutect2
- ENOX2 | c.1445T>G p.L482R (on ENST00000338144 / NM_001382520.1; = p.L453R on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57655288; called by muse, mutect2, varscan2
- ERLIN1 | c.888G>C p.K296N | Missense Mutation (SNP) | VAF 11/349 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100962141; called by muse, mutect2
- ERP44 | c.1036C>G p.Q346E | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.678); catalogued as COSV99315971; called by muse, mutect2
- ESYT3 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 9/243 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1311001681, COSV100004708; called by muse, mutect2
- FAAH2 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 13/140 reads (9%) | catalogued as COSV100887095; called by muse, mutect2
- FKBP4 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs927155815, COSV50009374; called by muse, mutect2
- FOCAD | c.15C>G p.I5M | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100619906, COSV58101708; called by muse, mutect2
- FRMD4A | c.829C>A p.P277T | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV52736139; called by muse, mutect2
- GALNT14 | c.386G>T p.R129M | Missense Mutation (SNP) | VAF 17/488 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100203935; called by muse, mutect2
- GCFC2 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs1416656266, COSV100319279; called by muse, mutect2
- GLYATL1 | c.736C>T p.R246* (on ENST00000317391 / NM_001354699.1; = p.R277* on NM_080661.4) | Nonsense Mutation (SNP) | VAF 8/84 reads (10%) | catalogued as rs141077035, COSV55609560; called by muse, mutect2, varscan2
- GNAI1 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs142908338; called by muse, mutect2
- GPNMB | c.1475C>T p.S492L (on ENST00000381990 / NM_001005340.2; = p.S480L on NM_002510.3) | Missense Mutation (SNP) | VAF 41/621 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs148779588, COSV51701879; called by muse, mutect2
- HDX | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs775667409, COSV52975890; called by muse, mutect2, varscan2
- HTATSF1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99511336; called by muse, mutect2
- IL6 | c.146C>G p.S49C | Missense Mutation (SNP) | VAF 23/545 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV99331325; called by muse, mutect2
- INTS6 | c.164T>C p.F55S | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100246844; called by muse, mutect2
- ITIH6 | c.3100G>A p.D1034N | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.703); catalogued as COSV99512703; called by muse, mutect2
- KCNIP1 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.023); catalogued as rs1222690098, COSV66177259; called by muse, mutect2
- KEL | c.1420C>T p.Q474* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as rs61729056, CM055969, COSV100786812, COSV100787090; called by mutect2, varscan2
- KLF7 | c.68C>G p.S23* | Nonsense Mutation (SNP) | VAF 11/160 reads (7%) | catalogued as COSV100518895; called by muse, mutect2
- LDB3 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 10/237 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99554590; called by muse, mutect2
- MCTP2 | c.678G>C p.K226N | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100537124; called by muse, mutect2
- MDM2 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773519801, COSV50699127, COSV50702443; called by muse, mutect2, varscan2
- MGME1 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66624394; called by muse, mutect2, varscan2
- MID1 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV58194267; called by muse, mutect2
- MRC2 | c.3122C>A p.S1041* | Nonsense Mutation (SNP) | VAF 28/228 reads (12%) | catalogued as COSV57642170; called by muse, mutect2, varscan2
- MYPN | c.2098C>T p.P700S | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62736773; called by muse, mutect2
- NIPBL | c.5392G>T p.E1798* | Nonsense Mutation (SNP) | VAF 10/262 reads (4%) | catalogued as COSV99238274; called by muse, mutect2
- NOMO1 | c.1421G>C p.R474T | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV55060058; called by muse, mutect2
- NUP62CL | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV100990916; called by muse, mutect2
- PIK3C2B | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 15/311 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV100914981; called by muse, mutect2
- PMF1 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 6/114 reads (5%) | catalogued as COSV100195653; called by muse, mutect2
- PNN | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1466943517, COSV99396944; called by muse, mutect2
- PRPF8 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 7/128 reads (5%) | catalogued as COSV59265424; called by muse, mutect2
- PSG4 | c.211C>A p.Q71K | Missense Mutation (SNP) | VAF 21/564 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV54939964; called by muse, mutect2
- PSMC2 | c.700G>C p.D234H | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99485083; called by muse, mutect2
- PSMF1 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as COSV99850187; called by muse, mutect2
- PTGS2 | c.164C>G p.S55* | Nonsense Mutation (SNP) | VAF 12/196 reads (6%) | catalogued as COSV100821637; called by muse, mutect2
- PTPN3 | c.1734C>A p.F578L | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.267); catalogued as COSV99355268; called by muse, mutect2
- PTPRA | c.2377G>C p.D793H | Missense Mutation (SNP) | VAF 12/372 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV99398897; called by muse, mutect2
- PYGB | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 130/680 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs751955480, COSV53820843; called by muse, varscan2
- REV1 | c.1511C>G p.S504* | Nonsense Mutation (SNP) | VAF 13/123 reads (11%) | catalogued as COSV51487877; called by muse, mutect2
- RYR2 | c.10625C>G p.S3542* | Nonsense Mutation (SNP) | VAF 16/289 reads (6%) | catalogued as COSV100767208, COSV63698497; called by muse, mutect2
- RYR3 | c.8380G>A p.G2794S (on ENST00000389232; = p.G2795S on NM_001036.6) | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as COSV101211812; called by muse, mutect2
- SAMD9 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV101180106; called by muse, mutect2
- SCN2A | c.1710A>T p.R570S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV51848688; called by muse, mutect2
- SGCA | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.503); catalogued as COSV100006501; called by muse, mutect2
- SLC38A1 | c.329C>A p.S110* | Nonsense Mutation (SNP) | VAF 8/85 reads (9%) | catalogued as COSV101284094; called by muse, mutect2
- SLC4A4 | c.1245G>A p.M415I (on ENST00000264485 / NM_001098484.3; = p.M371I on NM_003759.4) | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.094); catalogued as COSV52622663; called by muse, mutect2
- SLC6A15 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99879973; called by muse, mutect2
- SPATA31D1 | c.2402C>G p.S801C | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100782397; called by muse, mutect2
- SPOUT1 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as COSV63509614; called by muse, mutect2, varscan2
- SPTAN1 | c.4690G>C p.E1564Q | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100823159, COSV63987657; called by muse, mutect2
- SYP | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99602658, COSV99603002; called by muse, mutect2
- TBC1D3B | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 41/526 reads (8%) | catalogued as rs1416491529; called by muse, mutect2
- TCF4 | c.734C>G p.S245C | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100608891; called by muse, mutect2
- TLE1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV100916222; called by muse, mutect2
- TMEM120A | c.408C>G p.F136L | Missense Mutation (SNP) | VAF 6/194 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100115434; called by muse, mutect2
- TPPP2 | c.448A>G p.T150A | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.192); catalogued as COSV58795227; called by muse, mutect2, varscan2
- TRPA1 | c.920G>C p.G307A | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs1563401138, COSV100082812, COSV51568877; called by muse, mutect2
- TSTD2 | c.772G>C p.G258R | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100358905; called by muse, mutect2
- TTC21B | c.1169C>G p.S390C | Missense Mutation (SNP) | VAF 4/93 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV99691725; called by muse, mutect2
- TTC33 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100531773; called by muse, mutect2
- TTF2 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1376576108, COSV65632740, COSV65633548; called by muse, mutect2
- UNC13C | c.3077G>C p.G1026A | Missense Mutation (SNP) | VAF 21/247 reads (9%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as COSV99510073; called by muse, mutect2
- USP6 | c.2169G>C p.V723= | Splice Region (SNP) | VAF 13/195 reads (7%) | catalogued as COSV100002738; called by muse, mutect2
- VPS13A | c.6793G>A p.D2265N | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as COSV62426304, COSV62430603; called by muse, mutect2
- VPS54 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 16/280 reads (6%) | catalogued as COSV99707614; called by muse, mutect2
- VWA8 | c.2927C>T p.S976F | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99863438; called by muse, mutect2, varscan2
- WDR70 | c.493-1G>C p.X165_splice | Splice Site (SNP) | VAF 10/211 reads (5%) | catalogued as COSV99457074; called by muse, mutect2
- ZC3H12C | c.2111C>T p.P704L | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs778003491, COSV53707192; called by muse, mutect2, varscan2
- ZNF260 | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.644); catalogued as COSV101591026; called by muse, mutect2
- ZNF329 | c.1387G>T p.A463S | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as COSV100798652; called by muse, mutect2, varscan2
- ZNF329 | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.541); catalogued as rs1443134843, COSV100798653, COSV63773066; called by muse, mutect2
- ZNF510 | c.1495C>T p.Q499* | Nonsense Mutation (SNP) | VAF 9/111 reads (8%) | catalogued as COSV56298368, COSV56299388; called by muse, mutect2
- ACHE | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- RTEL1 | c.1901C>G p.S634* | Nonsense Mutation (SNP) | VAF 4/82 reads (5%) | called by muse, mutect2
- SYNPO2L | c.1798G>A p.G600S (on ENST00000394810 / NM_001114133.3; = p.G376S on NM_024875.5) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- AP1M2 | c.594C>T p.I198= | Silent (SNP) | VAF 6/121 reads (5%) | catalogued as COSV99140711; called by muse, mutect2
- CAMK2G | c.882C>T p.F294= | Silent (SNP) | VAF 6/178 reads (3%) | catalogued as COSV59482090, COSV99989336; called by muse, mutect2
- CD300LG | c.357G>A p.L119= | Silent (SNP) | VAF 14/204 reads (7%) | catalogued as COSV99517152; called by muse, mutect2
- CLIP3 | c.1077G>A p.K359= | Silent (SNP) | VAF 9/149 reads (6%) | catalogued as COSV99430750; called by muse, mutect2
- CMTM2 | c.609C>T p.F203= | Silent (SNP) | VAF 12/186 reads (6%) | catalogued as COSV99216332; called by muse, mutect2
- DNAH11 | c.1068G>A p.Q356= | Silent (SNP) | VAF 10/250 reads (4%) | catalogued as COSV100176221, COSV100180335; called by muse, mutect2
- ERBB3 | c.1104C>T p.L368= | Silent (SNP) | VAF 15/150 reads (10%) | catalogued as rs1358483166, COSV99915452; called by muse, mutect2
- ERN2 | c.1224G>A p.E408= | Silent (SNP) | VAF 9/125 reads (7%) | catalogued as COSV56835539; called by muse, mutect2
- FER1L6 | c.786C>T p.I262= | Silent (SNP) | VAF 8/189 reads (4%) | catalogued as COSV101205274; called by muse, mutect2
- GTF2E1 | c.1311C>G p.L437= | Silent (SNP) | VAF 17/260 reads (7%) | catalogued as rs1023341220, COSV99381660; called by muse, mutect2
- H4C3 | c.303C>T p.F101= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as rs778556234, COSV100619461, COSV58090166; called by muse, mutect2
- IFNAR1 | c.141G>C p.L47= | Silent (SNP) | VAF 7/218 reads (3%) | catalogued as COSV99531403; called by muse, mutect2
- KIAA1549L | c.1941G>C p.L647= (on ENST00000321505; = p.L944= on NM_012194.3) | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as COSV99682486, COSV99684113; called by muse, mutect2
- KLK12 | c.405C>T p.T135= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs746770863, COSV51578176; called by muse, mutect2, varscan2
- LSM4 | c.57G>A p.L19= | Silent (SNP) | VAF 23/424 reads (5%) | catalogued as COSV99416788; called by muse, mutect2
- MEP1A | c.1833G>A p.L611= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV57921468; called by muse, mutect2, varscan2
- MOV10 | c.1689C>G p.L563= | Silent (SNP) | VAF 10/208 reads (5%) | catalogued as COSV100659355; called by muse, mutect2
- MYH13 | c.3450C>A p.I1150= | Silent (SNP) | VAF 21/191 reads (11%) | catalogued as rs1309612889, COSV99351759; called by muse, mutect2, varscan2
- MYH2 | c.549A>G p.A183= | Silent (SNP) | VAF 8/210 reads (4%) | catalogued as COSV99819037; called by muse, mutect2
- NEDD9 | c.2169C>G p.L723= | Silent (SNP) | VAF 10/210 reads (5%) | catalogued as COSV101060730, COSV65220422; called by muse, mutect2
- NLRP11 | c.2586G>A p.L862= | Silent (SNP) | VAF 8/194 reads (4%) | catalogued as COSV100789607; called by muse, mutect2
- NOX4 | c.345C>T p.F115= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV99629232; called by muse, mutect2
- PIGV | c.585C>G p.L195= | Silent (SNP) | VAF 8/212 reads (4%) | catalogued as COSV99314713; called by muse, mutect2
- POFUT2 | c.339C>T p.L113= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as COSV57960175; called by muse, mutect2
- PRX | c.1725G>A p.P575= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as rs1043949955, COSV99397335; ClinVar: likely benign; called by muse, mutect2
- RBL2 | c.1389G>T p.L463= | Silent (SNP) | VAF 56/339 reads (17%) | catalogued as COSV100043194; called by muse, varscan2
- RIPOR1 | c.3396G>A p.E1132= (on ENST00000379312 / NM_001193522.2; = p.E1128= on NM_024519.4) | Silent (SNP) | VAF 8/162 reads (5%) | catalogued as COSV99242408; called by muse, mutect2
- SHANK2 | c.2688G>A p.P896= | Silent (SNP) | VAF 15/309 reads (5%) | catalogued as rs141694314; called by muse, mutect2
- SLC2A2 | c.102T>C p.P34= | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as COSV58587426; called by muse, mutect2, varscan2
- SMTN | c.330G>T p.L110= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as COSV100293773; called by muse, mutect2
- SOX5 | c.1581G>C p.L527= | Silent (SNP) | VAF 11/160 reads (7%) | catalogued as COSV100505476; called by muse, mutect2
- TADA2A | c.1110C>T p.L370= | Silent (SNP) | VAF 8/192 reads (4%) | catalogued as rs777295483; called by muse, mutect2
- TRRAP | c.2583C>G p.L861= | Silent (SNP) | VAF 7/126 reads (6%) | catalogued as COSV100721747, COSV62856472; called by muse, mutect2
- TTC3 | c.3468C>G p.L1156= | Silent (SNP) | VAF 10/183 reads (5%) | called by muse, mutect2
- USP40 | c.810G>A p.R270= | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as COSV99295609; called by muse, mutect2
- ZBTB21 | c.1164T>C p.D388= | Silent (SNP) | VAF 9/155 reads (6%) | catalogued as COSV100176825; called by muse, mutect2
- AGAP7P | n.1889C>G | RNA (SNP) | VAF 4/71 reads (6%) | called by muse, mutect2
- POR | c.*180G>A | 3'UTR (SNP) | VAF 10/125 reads (8%) | catalogued as COSV100115433; called by muse, mutect2
- ZFHX3 | c.-533+130C>G | Intron (SNP) | VAF 13/215 reads (6%) | catalogued as COSV101637443; called by muse, mutect2
